Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4893, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4893-01A (Primary Tumor).

Surgery Date: [REDACTED]

TCGA-CJ-4893

Pathology Report

DIAGNOSIS

(A) RIGHT RADICAL NEPHRECTOMY:
RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN NUCLEAR
GRADE 3 (5.2 CM),
CONFINED TO THE KIDNEY.

Ureteral and hilar vascular margins, free of tumor.

GROSS DESCRIPTION

(A) RIGHT RADICAL NEPHRECTOMY - A right kidney (11.0 x 7.0 x 3.7 cm) has a pale tan to brown tumor (5.2 x 4.7 x 3.0 cm) with a central scar. The tumor is well circumscribed with pushing area near the renal capsule and renal sinus. No lymph nodes are identified. Portions of the tumor are submitted for electron microscopy. A photograph is obtained.

SECTION CODE: A1, vascular and ureteral margin; A2-A4, tumor with renal sinus; A5, central scar; A6, A7, tumor with perinephric fat; A8-A10, tumor with adjacent renal parenchyma; A11-A12, distant normal kidney. [REDACTED]

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-83123

Source: NCI Genomic Data Commons file b051fcb6-5662-4434-8ad0-969e5ec1dce1 (TCGA-CJ-4893.2C374F76-B1DB-46EF-AE1A-2649740262EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).